Gene-level copy-number profile of tumor specimen TCGA-55-6971-01A from TCGA case TCGA-55-6971, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.5 years (21,734 days).
Specimen TCGA-55-6971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.71965e17-e0cc-4e86-bc61-edd79090148f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6971-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b71b70cd-829e-4e94-a64f-f536f1411f4d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 112; copy number 2: 14,353; copy number 3: 19,231; copy number 4: 21,923; copy number 5: 778; copy number 6: 2,329; copy number 7: 134; copy number 8: 73; copy number 9: 22; copy number 10: 55; copy number 11: 78; copy number 12: 222; copy number 13: 86; copy number 14: 110; copy number 15: 101; copy number 16: 22; copy number 22: 3; copy number 24: 58; copy number 29: 9; copy number 31: 3; copy number 32: 10; copy number 34: 3; copy number 35: 49; copy number 36: 11; copy number 42: 23; copy number 46: 11; copy number 53: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6971-01A-11D-1943-01): tumor purity 0.23, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 869 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,038,529–84,786,714, 22 genes, copy number 16: AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1.
- chr1:84,999,147–85,448,124, 9 genes, copy number 29 (within-gene range 2–29): DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1.
- chr1:143,343,180–143,652,215, 13 genes, copy number 9–12: AC242852.1, AC242852.2, AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P.
- chr1:149,754,301–151,459,494, 99 genes, copy number 14 (within-gene range 6–14) (broad region; genes not listed).
- chr10:60,026,298–61,496,499, 13 genes, copy number 22–53: ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1.
- chr11:77,216,558–78,582,156, 41 genes, copy number 24–32: GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr12:40,728,811–40,729,897, 1 gene, copy number 9: AC016144.1.
- chr12:55,684,568–56,688,408, 78 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr12:57,674,665–60,096,071, 50 genes, copy number 24–42: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1.
- chr12:61,668,302–61,702,771, 1 gene, copy number 36: AC090629.1.
- chr12:61,775,923–61,880,772, 2 genes, copy number 36: RPL21P104, KRT8P19.
- chr12:67,424,272–70,543,040, 74 genes, copy number 10–46 (broad region; genes not listed).
- chr17:43,211,835–44,916,937, 101 genes, copy number 15 (within-gene range 7–15) (broad region; genes not listed).
- chr17:45,475,363–46,975,524, 49 genes, copy number 35 (within-gene range 4–35): MIR4315-1, LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1, DND1P1, AC126544.2, AC126544.1, MAPK8IP1P2, RPS26P8, LINC02210, LINC02210-CRHR1, AC217774.1, AC217774.2, CRHR1, MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH, KANSL1, CR936218.1, KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11, WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2.
- chr18:31,937,533–37,236,242, 83 genes, copy number 13 (broad region; genes not listed).
- chr18:37,243,776–37,306,333, 3 genes, copy number 13: AC015961.2, AC090386.1, AC090386.2.
- chr19:42,234,583–46,639,161, 230 genes, copy number 9–12 (within-gene range 4–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
